Somatic mutation profile of tumor specimen 0DR20J from CCDI case PBCFIX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 11.2 years (4,105 days).
Specimen 0DR20J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23d83897-7af0-40d2-8f9e-cabbfff86d65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR1YN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/235f9b05-ea97-49b5-998c-1bd08f6386ac

The open-access MAF lists 167 somatic variants for this specimen: 108 protein-altering or splice-affecting, 28 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 28, Intron 12, 3'UTR 9, Splice Site 8, 5'UTR 8, Nonsense Mutation 5, Frame Shift Del 2, RNA 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADSB | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 15/244 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs1266747835, COSV62550543; called by muse, mutect2
- ANO7 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 82/524 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); catalogued as rs201638265, COSV51468946; called by muse, varscan2
- AP002512.3 | c.1130T>A p.V377E | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV54406460; called by muse, mutect2
- BMP4 | c.26T>C p.M9T | Missense Mutation (SNP) | VAF 49/522 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs746551997; called by muse, mutect2, varscan2
- CACNA1B | c.2071G>T p.V691F | Missense Mutation (SNP) | VAF 56/700 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1280758713; called by muse, mutect2
- CD177 | c.1026G>T p.M342I | Missense Mutation (SNP) | VAF 74/454 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1343878634; called by muse, mutect2, varscan2
- CHST5 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 200/596 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs572591635, COSV60337870; called by muse, varscan2
- CYP4F8 | c.717C>A p.F239L | Missense Mutation (SNP) | VAF 27/613 reads (4%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV100358225; called by muse, mutect2
- DHX29 | c.638A>T p.D213V | Missense Mutation (SNP) | VAF 86/483 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV52417193; called by muse, mutect2, varscan2
- DSG2 | c.1404G>T p.K468N | Missense Mutation (SNP) | VAF 96/770 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as COSV55202643; called by muse, mutect2, varscan2
- FRAS1 | c.5132C>T p.P1711L | Missense Mutation (SNP) | VAF 45/930 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs774882259, COSV53605495; called by muse, mutect2
- KDR | c.3365G>T p.G1122V | Missense Mutation (SNP) | VAF 25/544 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55778076; called by muse, mutect2
- LGSN | c.457T>A p.L153I | Missense Mutation (SNP) | VAF 139/747 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV101040279; called by muse, mutect2, varscan2
- LILRB2 | c.354A>G p.T118= | Splice Region (SNP) | VAF 23/518 reads (4%) | catalogued as COSV58748232; called by muse, mutect2
- MACC1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 38/1305 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1013042096; called by muse, mutect2
- MAN2C1 | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 59/328 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as COSV51227560; called by muse, mutect2, varscan2
- MAP2K3 | c.532G>C p.E178Q (on ENST00000342679 / NM_145109.3; = p.E149Q on NM_002756.4) | Missense Mutation (SNP) | VAF 228/1346 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.762); catalogued as COSV57577578; called by muse, mutect2
- MIOS | c.2314G>T p.V772F | Missense Mutation (SNP) | VAF 167/1277 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100402800; called by muse, mutect2, varscan2
- OR4X1 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 83/574 reads (14%) | catalogued as rs754782004; called by muse, mutect2, varscan2
- PLXNA4 | c.3158G>T p.S1053I | Missense Mutation (SNP) | VAF 38/1400 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as rs1270800921, COSV58145038; called by muse, mutect2
- POLR1B | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 28/666 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV99638714; called by muse, mutect2
- RYR1 | c.7207C>T p.R2403C | Missense Mutation (SNP) | VAF 20/739 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs1241302558, COSV62098375, COSV62106255; called by muse, mutect2
- SIRPB2 | c.964G>C p.D322H | Missense Mutation (SNP) | VAF 153/602 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.438); catalogued as COSV63122921, COSV63123714; called by muse, mutect2, varscan2
- TMEM63B | c.1318G>A p.V440I | Missense Mutation (SNP) | VAF 207/839 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as rs775072250, COSV99442441; called by muse, mutect2, varscan2
- UGT1A6 | c.1301+1G>T p.X434_splice | Splice Site (SNP) | VAF 23/302 reads (8%) | catalogued as CS051706; called by muse, mutect2
- USP7 | c.2869G>T p.E957* | Nonsense Mutation (SNP) | VAF 83/417 reads (20%) | catalogued as COSV100784460, COSV61214131; called by muse, mutect2, varscan2
- VAV3 | c.399A>C p.E133D | Missense Mutation (SNP) | VAF 53/1069 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as rs1465021659; called by muse, mutect2
- VPS28 | c.37+1G>T p.X13_splice | Splice Site (SNP) | VAF 103/227 reads (45%) | catalogued as rs1257500394; called by muse, mutect2, varscan2
- WDR19 | c.239A>G p.Y80C | Missense Mutation (SNP) | VAF 88/1096 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1228214710; called by muse, mutect2
- ZNF407 | c.1706G>A p.R569K | Missense Mutation (SNP) | VAF 68/1434 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs867190002; called by muse, mutect2
- ABCC11 | c.3258+1G>A p.X1086_splice | Splice Site (SNP) | VAF 32/604 reads (5%) | called by muse, mutect2
- AHNAK | c.6575A>G p.N2192S | Missense Mutation (SNP) | VAF 48/830 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2
- AMHR2 | c.1689T>A p.N563K | Missense Mutation (SNP) | VAF 20/696 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.4475A>G p.E1492G | Missense Mutation (SNP) | VAF 100/479 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ANKRD10 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- APOB | c.384-1G>T p.X128_splice | Splice Site (SNP) | VAF 36/478 reads (8%) | called by muse, mutect2
- ARHGEF6 | c.2036-2A>T p.X679_splice | Splice Site (SNP) | VAF 58/265 reads (22%) | called by muse, mutect2, varscan2
- B3GALNT2 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 19/556 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2
- BDP1 | c.6173A>T p.K2058M | Missense Mutation (SNP) | VAF 354/757 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- BMPER | c.768C>G p.C256W | Missense Mutation (SNP) | VAF 125/1051 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- C18orf25 | c.487A>T p.K163* | Nonsense Mutation (SNP) | VAF 147/1200 reads (12%) | called by muse, mutect2, varscan2
- C1QTNF9 | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C1QTNF9B | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 32/946 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CALR | c.122A>T p.K41I | Missense Mutation (SNP) | VAF 87/483 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- CDC27 | c.1973T>G p.F658C | Missense Mutation (SNP) | VAF 104/1118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CDK14 | c.703-1G>C p.X235_splice (on ENST00000380050 / NM_001287135.2; = p.X217_splice on NM_012395.3) | Splice Site (SNP) | VAF 18/454 reads (4%) | called by muse, mutect2
- CHST15 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 169/505 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- CLEC4F | c.6C>G p.D2E | Missense Mutation (SNP) | VAF 75/331 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- COQ6 | c.686_687del p.Q229Lfs*47 | Frame Shift Del (DEL) | VAF 135/465 reads (29%) | called by mutect2, pindel, varscan2
- CPNE3 | c.166A>T p.N56Y | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CREBBP | c.437C>G p.A146G | Missense Mutation (SNP) | VAF 31/407 reads (8%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.034); called by muse, mutect2
- CWH43 | c.890T>G p.M297R | Missense Mutation (SNP) | VAF 52/1116 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2
- DNAAF1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 169/632 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- DYDC2 | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2
- ECHS1 | c.55G>T p.V19F | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPHA5 | c.2935A>T p.M979L | Missense Mutation (SNP) | VAF 131/726 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ERBB3 | c.2478G>C p.E826D | Missense Mutation (SNP) | VAF 99/412 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FANCD2 | c.2369T>C p.L790P | Missense Mutation (SNP) | VAF 147/325 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FBXW5 | c.305A>T p.H102L | Missense Mutation (SNP) | VAF 22/958 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- FMN1 | c.2128G>C p.E710Q (on ENST00000616417 / NM_001277313.2; = p.E487Q on NM_001103184.4) | Missense Mutation (SNP) | VAF 81/1036 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- GAST | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 45/852 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2
- GIPR | c.578T>A p.L193Q | Missense Mutation (SNP) | VAF 86/695 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HGFAC | c.666G>C p.Q222H | Missense Mutation (SNP) | VAF 119/852 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- IDUA | c.1852T>A p.Y618N | Missense Mutation (SNP) | VAF 82/458 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IQUB | c.2174A>T p.K725M | Missense Mutation (SNP) | VAF 101/827 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- ITGB4 | c.2660T>G p.V887G | Missense Mutation (SNP) | VAF 54/1611 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- KCNC4 | c.841C>A p.L281M | Missense Mutation (SNP) | VAF 26/550 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- KLHL31 | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 60/930 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2
- KRTAP9-1 | c.377C>G p.T126S | Missense Mutation (SNP) | VAF 169/1275 reads (13%) | SIFT tolerated (0.68); called by muse, mutect2, varscan2
- LSS | c.75G>T p.W25C | Missense Mutation (SNP) | VAF 117/395 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCAT | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 52/536 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); called by muse, mutect2
- MED23 | c.3962T>A p.L1321* | Nonsense Mutation (SNP) | VAF 138/772 reads (18%) | called by muse, mutect2, varscan2
- METTL24 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 28/816 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- MIEF1 | c.101G>C p.G34A | Missense Mutation (SNP) | VAF 60/861 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- MTPAP | c.47C>A p.A16D | Missense Mutation (SNP) | VAF 26/520 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.224); called by muse, mutect2
- NOX4 | c.13T>C p.W5R | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2
- NPC1L1 | c.3970T>A p.S1324T | Missense Mutation (SNP) | VAF 168/1027 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR4A1 | c.160G>C p.E54Q (on ENST00000545748 / NM_001202234.1; = p.E13Q on NM_001202233.1) | Missense Mutation (SNP) | VAF 111/481 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NTRK3 | c.126G>C p.E42D | Missense Mutation (SNP) | VAF 77/351 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NUFIP2 | c.1664G>T p.G555V | Missense Mutation (SNP) | VAF 43/1863 reads (2%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.99); called by muse, mutect2
- PEX6 | c.2847G>T p.E949D | Missense Mutation (SNP) | VAF 97/491 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PGAP1 | c.2559A>C p.K853N | Missense Mutation (SNP) | VAF 101/368 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PLCG2 | c.3727A>C p.S1243R (on ENST00000359376; = p.Q1243P on NM_002661.5) | Missense Mutation (SNP) | VAF 67/721 reads (9%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2
- PLEKHN1 | c.1491C>A p.D497E (on ENST00000379409; = p.D445E on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/1036 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2
- PLET1 | c.196G>C p.V66L | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PODXL2 | c.1522A>T p.I508F | Missense Mutation (SNP) | VAF 36/717 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- PRDM9 | c.895A>T p.R299* | Nonsense Mutation (SNP) | VAF 15/442 reads (3%) | called by muse, mutect2
- PRKD1 | c.667T>C p.S223P | Missense Mutation (SNP) | VAF 105/699 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PRSS48 | c.301A>G p.K101E | Missense Mutation (SNP) | VAF 166/872 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.583_602del p.I195Efs*10 (on ENST00000421990 / NM_001136042.2; = p.I177Efs*10 on NM_025267.3) | Frame Shift Del (DEL) | VAF 156/1796 reads (9%) | called by mutect2, pindel
- RASGRP1 | c.1517T>A p.F506Y | Missense Mutation (SNP) | VAF 77/1014 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- RNF17 | c.316A>G p.T106A | Missense Mutation (SNP) | VAF 80/321 reads (25%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RNF213 | c.7592C>G p.S2531C | Missense Mutation (SNP) | VAF 62/1182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- SEPTIN14 | c.1227G>T p.M409I | Missense Mutation (SNP) | VAF 146/1143 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLC37A3 | c.507G>T p.W169C | Missense Mutation (SNP) | VAF 38/1420 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC6A9 | c.1406G>T p.G469V (on ENST00000360584 / NM_201649.4; = p.G415V on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 154/844 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAPBPL | c.905-2A>T p.X302_splice | Splice Site (SNP) | VAF 51/487 reads (10%) | called by muse, mutect2, varscan2
- TARBP1 | c.3978G>T p.M1326I | Missense Mutation (SNP) | VAF 104/596 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TBC1D32 | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 19/742 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- TESPA1 | c.1105C>G p.Q369E (on ENST00000316577 / NM_001098815.3; = p.Q231E on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/628 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.846); called by muse, mutect2
- TMC5 | c.2041G>C p.V681L (on ENST00000396229 / NM_001105248.1; = p.V435L on NM_024780.5) | Missense Mutation (SNP) | VAF 44/640 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.113); called by muse, mutect2
- TMEM235 | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 30/1020 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- UGT2B10 | c.463T>A p.C155S | Missense Mutation (SNP) | VAF 187/1011 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- VCAN | c.2921C>T p.P974L | Missense Mutation (SNP) | VAF 98/454 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- VCAN | c.5572T>A p.Y1858N | Missense Mutation (SNP) | VAF 179/868 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VPS39 | c.2208+1G>A p.X736_splice (on ENST00000348544 / NM_001301138.2; = p.X725_splice on NM_015289.5) | Splice Site (SNP) | VAF 42/562 reads (7%) | called by muse, mutect2
- WDCP | c.1444G>T p.V482F | Missense Mutation (SNP) | VAF 54/1050 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.116); called by muse, mutect2
- ZNF746 | c.1665C>G p.D555E | Missense Mutation (SNP) | VAF 28/940 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2
- ADPRHL1 | c.1104C>T p.D368= | Silent (SNP) | VAF 51/167 reads (31%) | catalogued as rs555614333; called by muse, mutect2, varscan2
- AGBL3 | c.2124C>T p.N708= | Silent (SNP) | VAF 40/1288 reads (3%) | called by muse, mutect2
- BCAR3 | c.2103C>G p.P701= | Silent (SNP) | VAF 18/528 reads (3%) | called by muse, mutect2
- CLTCL1 | c.3153C>T p.D1051= | Silent (SNP) | VAF 90/794 reads (11%) | catalogued as rs782212139, COSV54231909; called by muse, mutect2, varscan2
- DNAH2 | c.6234C>T p.H2078= | Silent (SNP) | VAF 145/417 reads (35%) | catalogued as rs1290834460; called by muse, mutect2, varscan2
- FBH1 | c.1638G>C p.G546= (on ENST00000362091 / NM_178150.3; = p.G597= on NM_032807.4) | Silent (SNP) | VAF 201/620 reads (32%) | called by muse, mutect2, varscan2
- FCGR2B | c.363C>T p.S121= | Silent (SNP) | VAF 36/1108 reads (3%) | catalogued as rs1488362136, COSV52680619, COSV52683752; called by muse, mutect2
- FOXA2 | c.282C>A p.A94= (on ENST00000377115 / NM_153675.3; = p.A100= on NM_021784.5) | Silent (SNP) | VAF 17/410 reads (4%) | catalogued as rs1039298494; called by muse, mutect2
- GGT2 | c.570C>A p.V190= | Silent (SNP) | VAF 97/261 reads (37%) | called by muse, mutect2, varscan2
- HPS5 | c.2172T>C p.C724= (on ENST00000349215 / NM_181507.2; = p.C610= on NM_007216.4) | Silent (SNP) | VAF 35/450 reads (8%) | called by muse, mutect2
- IFI44 | c.1131A>G p.R377= | Silent (SNP) | VAF 103/521 reads (20%) | called by muse, mutect2, varscan2
- IGSF3 | c.2391G>A p.K797= (on ENST00000369486 / NM_001007237.3; = p.K817= on NM_001542.4) | Silent (SNP) | VAF 18/635 reads (3%) | catalogued as rs1231836461; called by muse, mutect2
- KRT8 | c.148C>T p.L50= | Silent (SNP) | VAF 64/958 reads (7%) | called by muse, mutect2
- LAMA4 | c.4320T>C p.D1440= (on ENST00000230538 / NM_001105206.3; = p.D1433= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/879 reads (7%) | catalogued as rs1366384304; called by muse, mutect2
- NPAP1 | c.1416T>A p.I472= | Silent (SNP) | VAF 24/683 reads (4%) | called by muse, mutect2
- NPAS2 | c.2157C>G p.P719= | Silent (SNP) | VAF 68/633 reads (11%) | called by muse, mutect2, varscan2
- OXLD1 | c.228C>T p.P76= | Silent (SNP) | VAF 274/1291 reads (21%) | catalogued as COSV100235785; called by muse, mutect2, varscan2
- PTPN12 | c.1020C>A p.T340= | Silent (SNP) | VAF 37/1044 reads (4%) | called by muse, mutect2
- PUS7 | c.336T>C p.A112= | Silent (SNP) | VAF 123/878 reads (14%) | called by muse, mutect2, varscan2
- RASGRP2 | c.291T>A p.A97= | Silent (SNP) | VAF 21/618 reads (3%) | called by muse, mutect2
- RGSL1 | c.2331A>C p.S777= | Silent (SNP) | VAF 135/668 reads (20%) | called by muse, mutect2, varscan2
- RYR1 | c.8445C>A p.A2815= | Silent (SNP) | VAF 32/916 reads (3%) | called by muse, mutect2
- SERPINA9 | c.6A>C p.A2= | Silent (SNP) | VAF 140/674 reads (21%) | catalogued as COSV54073820; called by muse, mutect2, varscan2
- SLC25A25 | c.1137G>A p.V379= | Silent (SNP) | VAF 171/1000 reads (17%) | catalogued as rs746883992; called by muse, mutect2, varscan2
- STAB2 | c.1377A>G p.G459= | Silent (SNP) | VAF 121/595 reads (20%) | catalogued as rs752953089; called by muse, varscan2
- TRIM47 | c.1329G>C p.L443= | Silent (SNP) | VAF 27/975 reads (3%) | called by muse, mutect2
- TTN | c.70401A>C p.P23467= (on ENST00000591111; = p.P16043= on NM_003319.4) | Silent (SNP) | VAF 35/814 reads (4%) | called by muse, mutect2
- XIRP2 | c.549A>C p.P183= (on ENST00000628543; = p.P358= on NM_152381.6) | Silent (SNP) | VAF 22/536 reads (4%) | called by muse, mutect2
- ARHGEF40 | c.2640+82G>C | Intron (SNP) | VAF 14/214 reads (7%) | catalogued as rs1348614336; called by muse, mutect2
- C1GALT1C1L | c.*5T>A | 3'UTR (SNP) | VAF 11/390 reads (3%) | called by muse, mutect2
- CBS | c.316+670G>C | Intron (SNP) | VAF 58/186 reads (31%) | called by muse, mutect2, varscan2
- CCDC127 | c.*45A>T | 3'UTR (SNP) | VAF 28/411 reads (7%) | called by muse, mutect2
- CD72 | c.-29G>T | 5'UTR (SNP) | VAF 89/242 reads (37%) | called by muse, mutect2, varscan2
- COX7A2L | c.-802C>A | 5'UTR (SNP) | VAF 16/154 reads (10%) | called by muse, mutect2
- CPN1 | c.-10G>T | 5'UTR (SNP) | VAF 16/269 reads (6%) | called by muse, mutect2
- DCHS2 | n.4364T>A | RNA (SNP) | VAF 48/657 reads (7%) | called by muse, mutect2
- DGCR2 | c.*64G>T | 3'UTR (SNP) | VAF 40/396 reads (10%) | called by muse, mutect2
- DVL1 | c.*68G>C | 3'UTR (SNP) | VAF 39/182 reads (21%) | catalogued as rs1042392805; called by muse, mutect2, varscan2
- ECI2 | c.674+89T>C | Intron (SNP) | VAF 41/238 reads (17%) | called by muse, mutect2, varscan2
- ENAH | c.914-73C>T | Intron (SNP) | VAF 8/126 reads (6%) | catalogued as rs1369181714, COSV99490822; called by muse, mutect2
- GRM5 | c.*100G>T | 3'UTR (SNP) | VAF 17/189 reads (9%) | called by muse, mutect2, varscan2
- INSL6 | c.-27G>A | 5'UTR (SNP) | VAF 42/560 reads (8%) | catalogued as rs922976567; called by muse, mutect2
- KIFC3 | chr16:57802996 del CACGC | 5'Flank (DEL) | VAF 66/412 reads (16%) | called by mutect2, pindel, varscan2
- KNSTRN | c.-95C>G | 5'UTR (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- KRTAP4-1 | c.*96C>A | 3'UTR (SNP) | VAF 34/291 reads (12%) | called by muse, mutect2, varscan2
- LRP2 | c.1773-89T>A | Intron (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2
- MAP1LC3B2 | c.*84A>C | 3'UTR (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- MICALL2 | c.2312-20C>A | Intron (SNP) | VAF 25/458 reads (5%) | called by muse, mutect2
- MUCL3 | c.946+1043T>G | Intron (SNP) | VAF 123/1082 reads (11%) | called by mutect2, varscan2
- P2RY8 | c.*6G>T | 3'UTR (SNP) | VAF 32/514 reads (6%) | called by muse, mutect2
- PPARG | c.-57G>C | 5'UTR (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- PSG7 | c.710-47A>C | Intron (SNP) | VAF 22/215 reads (10%) | called by muse, mutect2
- PSMD9 | c.556-66G>C | Intron (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- SGCE | c.218-44C>T | Intron (SNP) | VAF 75/475 reads (16%) | catalogued as rs1475374804; called by muse, mutect2, varscan2
- SRPRA | c.365+27A>T | Intron (SNP) | VAF 101/265 reads (38%) | called by muse, mutect2, varscan2
- TAFA4 | c.-6C>T | 5'UTR (SNP) | VAF 72/285 reads (25%) | catalogued as rs749613557; called by muse, mutect2, varscan2
- TLX1 | c.*77C>A | 3'UTR (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- TXNIP | c.989-32G>A | Intron (SNP) | VAF 28/856 reads (3%) | called by muse, mutect2
- UCMA | c.-49C>T | 5'UTR (SNP) | VAF 43/137 reads (31%) | catalogued as rs370480856; called by muse, mutect2, varscan2
